Somatic mutation profile of tumor specimen ALCH-B0CS-TTP1-A (aliquot ALCH-B0CS-TTP1-A-2-0-D-A709-36) from ALCHEMIST case ALCH-B0CS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,409 days).
Specimen ALCH-B0CS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aed7673f-539e-4786-ae63-2f4dd04703a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CS-NB1-A (Blood Derived Normal), aliquot ALCH-B0CS-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e11d9b29-b46f-498a-a215-39ccef35641b

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALYREF | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, varscan2
- LEMD3 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.147); called by muse, mutect2
- METTL23 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- BORCS7 | c.9G>A p.A3= | Silent (SNP) | VAF 15/324 reads (5%) | catalogued as rs962046337; called by muse, mutect2
- CES2 | c.981G>T p.L327= | Silent (SNP) | VAF 12/331 reads (4%) | called by muse, mutect2
- KRTAP10-12 | c.132G>A p.P44= | Silent (SNP) | VAF 9/217 reads (4%) | catalogued as rs373976770; called by muse, mutect2
- LRRCC1 | c.1653C>G p.L551= | Silent (SNP) | VAF 10/290 reads (3%) | called by muse, mutect2
- MYF5 | c.567T>C p.D189= | Silent (SNP) | VAF 16/415 reads (4%) | called by muse, mutect2
